Somatic mutation profile of tumor specimen TCGA-EJ-5521-01A (aliquot TCGA-EJ-5521-01A-01D-1576-08) from TCGA case TCGA-EJ-5521, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.8 years (23,304 days).
Specimen TCGA-EJ-5521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24ca6b30-8a58-448f-a462-edd5df2482ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5521-10A (Blood Derived Normal), aliquot TCGA-EJ-5521-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11f9cc6a-9ecc-49a5-93eb-e55259fc90a7

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 15, Frame Shift Ins 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs752801010, COSV66925861; called by muse, mutect2, varscan2
- AHNAK2 | c.8558A>C p.Q2853P | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60917767; called by muse, mutect2
- BRINP3 | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV66526996; called by muse, mutect2
- CAPN3 | c.738T>G p.S246R | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58822817; called by muse, mutect2
- CDC40 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57010099; called by muse, mutect2, varscan2
- CHRND | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs148869069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLIC2 | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58936986; called by muse, mutect2, varscan2
- DSCAM | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs770132126, COSV68020895; called by muse, mutect2, varscan2
- ERMP1 | c.2228T>G p.L743R | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV53037748; called by muse, mutect2
- HIPK1 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.775); catalogued as COSV65785015; called by muse, mutect2
- LIMK2 | c.1232G>C p.G411A | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59182850; called by muse, mutect2
- OR2T3 | c.702T>A p.N234K | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.426); catalogued as COSV62082648; called by muse, mutect2
- PPARD | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776822185, COSV61099998; called by muse, mutect2, varscan2
- PPP2R3A | c.2771C>T p.S924F | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.767); catalogued as COSV53864907; called by muse, mutect2
- RRBP1 | c.2071A>T p.K691* (on ENST00000377813 / NM_001365613.2; = p.K258* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 12/228 reads (5%) | catalogued as COSV55701577; called by muse, mutect2
- RTP3 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56123975; called by muse, mutect2, varscan2
- SIK3 | c.2854A>G p.T952A (on ENST00000445177 / NM_001366686.2; = p.T910A on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.001); catalogued as rs141671439, COSV52615928; called by muse, mutect2, varscan2
- SIK3 | c.790A>G p.N264D (on ENST00000445177 / NM_001366686.2; = p.N270D on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV52615951; called by muse, mutect2
- SLC12A1 | c.2659C>T p.H887Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs761522314, COSV66795649; called by muse, mutect2, varscan2
- SLC35F5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV55518798; called by muse, mutect2, varscan2
- SLCO1C1 | c.1530C>A p.N510K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1269241735, COSV56873826; called by muse, mutect2, varscan2
- TAL2 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183751696, COSV61883852; called by muse, mutect2, varscan2
- TOM1L1 | c.747G>T p.M249I | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV61947873; called by muse, mutect2, varscan2
- TPST1 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as rs142506783; called by muse, mutect2
- TSHZ3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 4/103 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV53673461; called by muse, mutect2
- TTN | c.24934G>A p.G8312S (on ENST00000591111; = p.G7385S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | PolyPhen probably damaging (1); catalogued as COSV60113340; called by muse, mutect2, varscan2
- WDR17 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs189140426, COSV54575558, COSV54576674; called by muse, mutect2, varscan2
- NCAM2 | c.406dup p.C136Lfs*4 | Frame Shift Ins (INS) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- TBL1XR1 | c.540dup p.S181* | Frame Shift Ins (INS) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- FAT4 | c.9603T>C p.Y3201= | Silent (SNP) | VAF 10/159 reads (6%) | catalogued as COSV58689558; called by muse, mutect2
- HLTF | c.2145T>A p.I715= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as COSV59501296; called by muse, mutect2, varscan2
- KIRREL1 | c.1935C>T p.S645= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs369421466; called by muse, mutect2, varscan2
- NALCN | c.249G>A p.T83= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs145910377; called by muse, mutect2, varscan2
- NBAS | c.5877G>A p.E1959= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as COSV55724573; called by muse, mutect2
- NEUROD4 | c.753C>A p.G251= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as COSV54472082, COSV54472760; called by muse, mutect2, varscan2
- NIPAL4 | c.843C>T p.Y281= | Silent (SNP) | VAF 27/357 reads (8%) | catalogued as rs753530888, COSV57431328; ClinVar: uncertain significance; called by muse, mutect2
- NPAS2 | c.2067C>T p.D689= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs146215582; called by muse, mutect2, varscan2
- OR2V2 | c.237G>A p.V79= | Silent (SNP) | VAF 15/284 reads (5%) | catalogued as COSV60315704; called by muse, mutect2
- OR51F1 | c.117T>A p.P39= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV58579982, COSV58580950; called by muse, mutect2, varscan2
- PHTF2 | c.1464C>T p.N488= (on ENST00000248550 / NM_001366089.1; = p.N450= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV50328110; called by muse, mutect2, varscan2
- PRKACG | c.30C>T p.T10= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs541637720, COSV55240763; called by muse, mutect2, varscan2
- PTPN6 | c.267C>T p.R89= | Silent (SNP) | VAF 12/195 reads (6%) | catalogued as rs901204561, COSV59684841; called by muse, mutect2
- S1PR5 | c.270C>T p.A90= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100330756, COSV61013956; called by muse, mutect2
- ST6GALNAC6 | c.588C>T p.L196= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs140405426; called by muse, mutect2
- YWHAH | c.87+5572C>T | Intron (SNP) | VAF 30/144 reads (21%) | catalogued as rs1569275416, COSV50708428; called by muse, mutect2, varscan2
